Somatic mutation profile of tumor specimen TCGA-BS-A0UT-01A (aliquot TCGA-BS-A0UT-01A-11D-A10B-09) from TCGA case TCGA-BS-A0UT, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 62.4 years (22,775 days).
Specimen TCGA-BS-A0UT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 37ba6961-6875-4d66-8c6c-1e3c0a3788fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BS-A0UT-10A (Blood Derived Normal), aliquot TCGA-BS-A0UT-10A-01D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47d24cab-1db2-46f5-8c3b-33e381df29b7

The open-access MAF lists 41 somatic variants for this specimen: 35 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 26, Silent 6, Nonsense Mutation 3, Splice Site 2, In Frame Del 2, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, mutect2, varscan2
- PIK3CA | c.1634A>C p.E545A | Missense Mutation (SNP) | VAF 23/49 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SOX17 | c.1208G>T p.S403I | Missense Mutation (SNP) | VAF 27/56 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52024163; called by muse, mutect2, varscan2
- SPOP | c.349A>G p.M117V | Missense Mutation (SNP) | VAF 81/200 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV61652945; called by muse, mutect2, varscan2
- BPIFA2 | c.646-1G>A p.X216_splice | Splice Site (SNP) | VAF 203/331 reads (61%) | catalogued as COSV53611538; called by muse, mutect2, varscan2
- BRINP3 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 124/184 reads (67%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as rs200159768, COSV66530148; called by muse, mutect2, varscan2
- BRWD1 | c.338del p.R113Lfs*29 | Frame Shift Del (DEL) | VAF 30/73 reads (41%) | catalogued as COSV58123191; called by mutect2, pindel, varscan2
- CACNA2D2 | c.595A>T p.N199Y | Missense Mutation (SNP) | VAF 108/275 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); catalogued as COSV56565705; called by muse, mutect2, varscan2
- CHD9 | c.1080C>A p.N360K | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); catalogued as COSV68298948; called by muse, mutect2, varscan2
- DDX50 | c.964_966del p.T322del | In Frame Del (DEL) | VAF 39/97 reads (40%) | catalogued as COSV65292769; called by mutect2, pindel, varscan2
- DNAAF3 | c.22G>C p.G8R (on ENST00000524407 / NM_001256715.2; = p.G55R on NM_178837.4) | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1166821702, COSV62830738; called by muse, mutect2, varscan2
- DYRK2 | c.1190C>A p.A397D (on ENST00000344096 / NM_006482.3; = p.A324D on NM_003583.4) | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.463); catalogued as COSV59846808; called by muse, mutect2, varscan2
- EP400 | c.5089C>G p.P1697A | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.173); catalogued as COSV57777542; called by muse, mutect2, varscan2
- FOXD4 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as rs753190134, COSV58701114; called by muse, mutect2, varscan2
- FSTL5 | c.1718T>C p.V573A | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV60207526; called by muse, mutect2, varscan2
- GAK | c.3262G>A p.D1088N | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs745660937, COSV58506609; called by muse, mutect2, varscan2
- GDPD2 | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs777315658, COSV65533522; called by muse, mutect2, varscan2
- INHBC | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.207); catalogued as rs1566551952, COSV59004807; called by muse, mutect2, varscan2
- KNTC1 | c.5178C>T p.D1726= | Splice Region (SNP) | VAF 17/40 reads (43%) | catalogued as rs983949034, COSV61081608; called by muse, varscan2
- MAP3K5 | c.1010_1015del p.L337_K339delins* | Nonsense Mutation (DEL) | VAF 26/75 reads (35%) | catalogued as COSV62890210; called by mutect2, pindel, varscan2
- MFAP1 | c.460C>T p.Q154* | Nonsense Mutation (SNP) | VAF 113/258 reads (44%) | catalogued as COSV51039636; called by muse, mutect2, varscan2
- MSN | c.118A>G p.R40G | Missense Mutation (SNP) | VAF 80/210 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV64304645; called by muse, mutect2, varscan2
- NDNF | c.29G>T p.W10L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as COSV65634053; called by muse, mutect2, varscan2
- NPAS1 | c.503T>C p.I168T | Missense Mutation (SNP) | VAF 63/130 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV101463923, COSV71384121; called by muse, mutect2, varscan2
- PACSIN3 | c.1229G>T p.R410L | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV100096445, COSV54066647; called by muse, mutect2, varscan2
- PPWD1 | c.1259A>T p.E420V | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as COSV54334396; called by muse, mutect2, varscan2
- RANBP2 | c.7148A>G p.N2383S | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51703681; called by muse, mutect2, varscan2
- RASGRF1 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.974); catalogued as rs199930552, COSV69180760; called by muse, mutect2, varscan2
- RGS5 | c.35G>A p.C12Y | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV58352887, COSV58353328; called by muse, mutect2, varscan2
- SI | c.5197+2T>G p.X1733_splice | Splice Site (SNP) | VAF 34/75 reads (45%) | catalogued as COSV52287210; called by muse, mutect2, varscan2
- SKP2 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs768455603, COSV57043123; called by muse, mutect2, varscan2
- TNNI3K | c.2162A>G p.E721G | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.073); catalogued as COSV53950139; called by muse, mutect2, varscan2
- UPRT | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64920376; called by muse, mutect2, varscan2
- WDR89 | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 91/200 reads (46%) | catalogued as COSV50827156; called by muse, mutect2, varscan2
- MED13L | c.6580_6585del p.V2194_H2195del | In Frame Del (DEL) | VAF 5/51 reads (10%) | called by mutect2, pindel, varscan2
- C11orf53 | c.189C>T p.Y63= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as rs1354020358, COSV54722044; called by muse, mutect2, varscan2
- CLASRP | c.9C>T p.H3= | Silent (SNP) | VAF 102/216 reads (47%) | catalogued as COSV55511390; called by muse, mutect2, varscan2
- GLT6D1 | c.657G>A p.P219= | Silent (SNP) | VAF 37/93 reads (40%) | catalogued as rs201383603, COSV65627181; called by muse, mutect2, varscan2
- MC1R | c.561C>T p.A187= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs370306913; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TECTA | c.4548C>T p.I1516= | Silent (SNP) | VAF 37/94 reads (39%) | catalogued as COSV50739904; called by muse, mutect2, varscan2
- WDR75 | c.2232T>C p.A744= | Silent (SNP) | VAF 77/124 reads (62%) | catalogued as COSV59106144; called by muse, mutect2, varscan2
